Gene-level copy-number profile of tumor specimen TCGA-18-3408-01A from TCGA case TCGA-18-3408, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.1 years (28,171 days).
Specimen TCGA-18-3408-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.93fb49c4-6433-4061-a09c-1705f23eb3c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-18-3408-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d260852c-42c8-4f24-a1d8-8d028d867531

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,163; copy number 2: 44,360; copy number 3: 3,296; copy number 4: 1,543; copy number 5: 185; copy number 6: 9; copy number 7: 3; copy number 12: 45; copy number 14: 93; copy number 15: 14; copy number 16: 83; copy number 27: 2; copy number 28: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-18-3408-01A-01D-0978-01): tumor purity 0.76, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 457 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:147,844,123–152,465,780, 106 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:164,001,606–179,338,583, 195 genes, copy number 5–15 (broad region; genes not listed).
- chr3:180,989,762–181,836,880, 1 gene, copy number 28 (within-gene range 3–28): SOX2-OT.
- chr3:181,505,075–185,489,094, 105 genes, copy number 16–28 (within-gene range 4–28) (broad region; genes not listed).
- chr7:54,676,217–56,229,782, 50 genes, copy number 7–27: AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, AC006970.2, CCNJP1.

Autosomal genes at a single copy (total copy number 1): 8,643. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
